Gene-level copy-number profile of tumor specimen ALCH-B3GJ-TTP1-A from ALCHEMIST case ALCH-B3GJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Non-small cell carcinoma; Age at diagnosis: 63.2 years (23,093 days).
Specimen ALCH-B3GJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a51dcbdf-0fab-42ee-af93-a3fe7074fe5e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3GJ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/0ffe62b6-350c-440b-8107-a23c485dae34

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 662; copy number 1: 58; copy number 2: 11,886; copy number 3: 14,824; copy number 4: 18,595; copy number 5: 6,493; copy number 6: 4,234; copy number 7: 1,764; copy number 8: 175; copy number 9: 144; copy number 10: 29; copy number 11: 18; copy number 12: 20; copy number 15: 2; copy number 24: 1.

Homozygous deletions (total copy number 0; autosomes only): 49 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:65,872,815–66,009,200, 4 genes (within-gene range 0–2): MAGI1-IT1, MAGI1-AS1, Y_RNA, AC106827.1.
- chr4:183,099,257–183,322,426, 4 genes: WWC2, WWC2-AS1, CLDN22, CLDN24.
- chr5:59,039,761–59,063,503, 1 gene (within-gene range 0–3): AC092343.1.
- chr5:71,032,670–71,259,238, 6 genes: GTF2H2, OCLNP1, NAIPP4, CDH12P4, GUSBP9, GUSBP17.
- chr8:64,091–1,708,476, 27 genes (within-gene range 0–4): AC144568.1, AC144568.2, AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2.
- chr9:128,340,527–128,361,470, 2 genes: SLC27A4, TMSB4XP4.
- chr11:11,020,883–11,183,611, 3 genes (within-gene range 0–2): LINC02752, AC111188.1, AC111188.2.
- chr14:69,611,596–69,715,144, 2 genes (within-gene range 0–5): SUSD6, AL133445.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 214 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:36,531,805–36,656,941, 2 genes, copy number 11 (within-gene range 7–11): FEZ2, AC007363.1.
- chr6:37,353,979–38,715,217, 22 genes, copy number 11–12: RNF8, RN7SL273P, CMTR1, CCDC167, LINC02520, AL353597.2, AL353597.1, MIR4462, AL353597.3, MDGA1, AL121574.1, ZFAND3, RN7SL285P, RNVU1-33, AL589655.1, BTBD9, AL033518.1, BTBD9-AS1, Y_RNA, AL079341.1, GLO1, AL391415.1.
- chr6:39,792,298–40,276,237, 7 genes, copy number 9: DAAM2, AL592158.1, DAAM2-AS1, MOCS1, TUBBP9, FO393411.1, AL139275.2.
- chr11:129,591,493–132,336,822, 41 genes, copy number 9 (within-gene range 5–10): AP003500.1, LINC01395, AP003327.2, AP003327.1, TMEM45B, NFRKB, PRDM10, LINC00167, AP003041.1, ELOBP2, AP003041.2, APLP2, RPL34P21, U4, ST14, ZBTB44, NDUFAF2P2, DDX18P5, RN7SL778P, ZBTB44-DT, ADAMTS8, ADAMTS15, AP004371.1, BAK1P2, MIR8052, LINC02873, PPP1R10P1, LINC02551, SNX19, AP003486.1, RN7SL167P, AP002856.3, AP002856.1, AP002856.4, AP002856.2, NTM, RNU6ATAC12P, AP003025.1, AP003025.2, NTM-AS1, AP004372.1.
- chr14:63,761,899–64,338,112, 6 genes, copy number 10–11 (within-gene range 5–11): SYNE2, AL161670.1, RPS28P1, Y_RNA, ESR2, MIR548H1.
- chr14:90,820,064–90,828,199, 1 gene, copy number 10: LINC02321.
- chr14:104,376,530–104,937,761, 25 genes, copy number 10 (within-gene range 7–10): AL512357.1, RNU6-684P, CEND1P1, TMEM179, C14orf180, BX927359.1, AL583722.2, LINC02280, MIR4710, INF2, AL583722.3, ADSS1, SIVA1, AL583722.1, AKT1, ZBTB42, AL590326.1, LINC00638, RPS26P49, RPS2P4, AL583810.2, AL583810.1, CEP170B, AL583810.3, PLD4.
- chr14:105,398,538–105,450,106, 2 genes, copy number 10 (within-gene range 7–10): TEX22, AL928654.1.
- chr16:66,841,433–67,101,058, 14 genes, copy number 9 (within-gene range 5–9): AC044802.2, CA7, PDP2, CDH16, RRAD, CIAO2B, CES2, AC009084.1, AC009084.3, CES3, CES4A, AC009084.2, RN7SL543P, CBFB.
- chr16:88,570,403–90,222,851, 82 genes, copy number 9 (broad region; genes not listed).
- chr17:64,936,485–65,458,408, 12 genes, copy number 12–24: AC103810.4, AC037487.4, AC103810.8, AC037487.1, AC037487.3, SLC16A6P1, AMZ2P1, GNA13, AC037487.2, RGS9, AC060771.1, LINC02563.

Autosomal genes at a single copy (total copy number 1): 58. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
